Surgical pathology report (de-identified scan), TCGA case TCGA-3H-AB3U, project TCGA-MESO (Mesothelioma), tissue source site MD Anderson Cancer Center, specimen TCGA-3H-AB3U-01A (Primary Tumor).

[page 1 of 2]
Accession: [REDACTED]
Specimen Date/Time: [REDACTED]

DIAGNOSIS

- (A) 4R LYMPH NODE:
One lymph node, uninvolved (0/1)
- (B) 4L LYMPH NODE:
One lymph node, uninvolved (0/1)
- (C) STATION 7 LYMPH NODE:
One lymph node, uninvolved (0/1)
- (D, E) PLEURA AND PARIETAL PLEURA, BIOPSIES:
EPITHELIOID MALIGNANT MESOTHELIOMA INVOLVING FIBROADIPOSE TISSUE

ICD O-3

Mesothelioma, epithelioid
malignant 905213
Site: Pleura NOS C38.4
Op 6/13/14

GROSS DESCRIPTION

- (A) 4R LYMPH NODE - A single lymph node measuring 0.8 cm in its greatest dimension. Entirely submitted in cassette A.
- (B) 4L LYMPH NODE - A single fragment of fatty tissue measuring 0.5 cm in its greatest dimension. Entirely submitted in cassette B.
- (C) STATION 7 - A single fragment of fatty tissue measuring 0.5 cm in its greatest dimension. Entirely submitted in cassette C.
- (D) PLEURA - Two fragments of tan tissue ranging from 0.5 up to 1.1 cm in greatest dimension. Entirely submitted in cassette D
- (E) PARIETAL PLEURA - A single fragment of tan soft tissue measuring 0.6 cm in its greatest dimension. Entirely submitted in cassette E.

CLINICAL HISTORY

Mesothelioma.

SNOMED CODES

T-29000, M-90503

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration"
Entire report and diagnosis completed by:

These tests have not been

-----END OF REPORT-----

[page 2 of 2]
[REDACTED] M
Accession: [REDACTED]
Specimen Date/Time:

Source: NCI Genomic Data Commons file 489764d1-f21c-45cc-b0f7-c772f2d68b1d (TCGA-3H-AB3U.BA7F7532-3137-4D3B-8F51-3F5ABFC03471.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).